Somatic mutation profile of tumor specimen TCGA-DH-A7UT-01A (aliquot TCGA-DH-A7UT-01A-12D-A34A-08) from TCGA case TCGA-DH-A7UT, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 30.2 years (11,014 days).
Specimen TCGA-DH-A7UT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 038c53a3-6af9-4a3c-8099-f35ca30217e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A7UT-10A (Blood Derived Normal), aliquot TCGA-DH-A7UT-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee67d424-0bab-4ab5-9874-05583c2dc221

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 35/100 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 24/37 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- KRTCAP3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1439373605, COSV99274997, COSV99275253; called by muse, mutect2, varscan2
- NCF4 | c.585T>A p.D195E | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.147); catalogued as COSV50620918, COSV99957312; called by muse, mutect2, varscan2
- NIPBL | c.6166C>G p.P2056A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071042, COSV99240387; called by muse, mutect2, varscan2
- NIPBL | c.6538T>G p.F2180V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99240390; called by muse, mutect2, varscan2
- PROKR2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs142008002, CM1410088; called by muse, mutect2, varscan2
- RNF133 | c.651G>C p.R217S | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV100411593; called by muse, mutect2, varscan2
- SLC32A1 | c.503C>G p.A168G | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as COSV54146280, COSV99462168; called by muse, mutect2, varscan2
- SNRNP200 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100107544; called by muse, mutect2, varscan2
- UGT1A1 | c.473C>G p.P158R | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.148); catalogued as rs1218181857, COSV100530218; called by muse, mutect2
- UNC5CL | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs910272714, COSV55111210, COSV99770773; called by muse, mutect2, varscan2
- WIPF2 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV60275080; called by muse, mutect2, varscan2
- ZNF551 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs139249482; called by muse, mutect2
- ITGAV | c.807T>C p.F269= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs754911086, COSV99654834; called by muse, mutect2, varscan2
- KIAA0408 | c.285G>A p.T95= | Silent (SNP) | VAF 53/151 reads (35%) | catalogued as rs1191680559, COSV64106096; called by muse, mutect2, varscan2
- LAIR2 | c.253A>C p.R85= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100003265; called by muse, mutect2, varscan2
- ZAN | c.5025G>A p.Q1675= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs779163318, COSV100769665; called by muse, mutect2
